Gene-level copy-number profile of tumor specimen TCGA-EE-A20I-06A from TCGA case TCGA-EE-A20I, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.1 years (29,259 days).
Specimen TCGA-EE-A20I-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c791209c-d7da-4b92-b692-c260406ab1ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A20I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec87d687-6d7c-40a5-88f2-67539b1336a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 19,908; copy number 2: 35,201; copy number 3: 4,455; copy number 4: 126; copy number 5: 30; copy number 6: 34; copy number 7: 47; copy number 8: 5; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A20I-06A-11D-A194-01): tumor purity 0.78, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,577,359, 1 gene: AC007223.1.
- chr16:62,187,540–62,187,646, 1 gene: RNU6-21P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–443,160, 17 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1.
- chr5:1,708,785–2,119,926, 14 genes, copy number 6 (within-gene range 2–6): MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2.
- chr5:2,712,591–2,755,397, 4 genes, copy number 8: LSINCT5, AC091891.1, IRX2, C5orf38.
- chr5:4,012,708–4,147,429, 3 genes, copy number 5: AC025773.1, AC025187.1, LINC02063.
- chr5:17,065,598–17,276,843, 6 genes, copy number 5 (within-gene range 2–5): BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2.
- chr5:19,233,366–19,234,487, 1 gene, copy number 6: HSPD1P15.
- chr5:20,158,662–20,347,972, 3 genes, copy number 6: AC093303.1, AC094103.1, CDH18-AS1.
- chr5:22,580,225–22,766,824, 2 genes, copy number 5: GCNT1P2, AC091938.1.
- chr5:36,098,407–36,347,157, 8 genes, copy number 9 (within-gene range 2–9): LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1.
- chr5:45,890,216–45,895,970, 1 gene, copy number 6: AC122694.1.
- chr7:131,493,964–132,087,992, 11 genes, copy number 6: AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1.
- chr10:14,819,245–15,371,289, 21 genes, copy number 7: CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1.
- chr10:16,207,821–16,207,927, 1 gene, copy number 8: RNU6-1075P.
- chr10:16,436,943–16,539,737, 4 genes, copy number 5: PTER, RNU2-18P, C1QL3, AL353576.1.
- chr10:20,350,049–20,552,046, 3 genes, copy number 6: AMD1P1, AL590032.1, MIR4675.
- chr10:24,157,835–24,158,781, 1 gene, copy number 6: NUP35P1.
- chr10:24,275,685–24,275,781, 1 gene, copy number 7: MIR603.
- chr10:24,583,609–26,212,532, 21 genes, copy number 5–7: ARHGAP21, RNA5SP305, AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A.
- chr10:30,403,197–30,461,833, 2 genes, copy number 5 (within-gene range 1–5): CCND3P1, MAP3K8.

Autosomal genes at a single copy (total copy number 1): 17,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
